ALCHEMIST case ALCH-B73V — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/7fbfa1a9-c9b1-4513-947c-b77c71529f25

Demographics
Sex at birth: female.

Diagnoses (1)
1. Adenocarcinoma, NOS: Age at diagnosis: 80.2 years (29,298 days).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-B73V-NB1-A: Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-B73V-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-B73V-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 13; Percent tumor nuclei: 31; Percent normal cells: 74; Percent necrosis: 0; Percent stromal cells: 13; Percent lymphocyte infiltration: 54; Percent monocyte infiltration: 4; Percent neutrophil infiltration: 0.
